Somatic mutation profile of tumor specimen C3L-04090-01 (aliquot CPT0265630007) from CPTAC case C3L-04090, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.5 years (26,123 days).
Specimen C3L-04090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 123495f0-527f-47cf-97bb-73697f297ca0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04090-31 (Blood Derived Normal), aliquot CPT0264100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17344b5f-2dc7-424c-a3fa-aabab767065f

The open-access MAF lists 88 somatic variants for this specimen: 56 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 26, Frame Shift Del 4, Intron 4, Nonsense Mutation 3, In Frame Ins 1, Splice Region 1, Splice Site 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1566G>C p.E522D | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV100710811, COSV61264418; called by muse, mutect2, varscan2
- AHNAK2 | c.10315G>A p.V3439M | Missense Mutation (SNP) | VAF 248/584 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs760627353, COSV60914651; called by muse, mutect2, varscan2
- BMT2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99774831; called by muse, mutect2, varscan2
- CILP2 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs767287963, COSV52280992; called by muse, mutect2, varscan2
- CIR1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59597308; called by muse, mutect2, varscan2
- CNTNAP2 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 96/345 reads (28%) | catalogued as COSV100673564; called by muse, mutect2, varscan2
- CPAMD8 | c.2936C>T p.A979V (on ENST00000651564; = p.A932V on NM_015692.5) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs539938043; called by muse, mutect2, varscan2
- CSMD2 | c.5194G>A p.A1732T | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.916); catalogued as COSV99595680; called by muse, mutect2, varscan2
- DSP | c.8278G>A p.A2760T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs991726607, COSV60940984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMB | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1387981516; called by muse, mutect2, varscan2
- FGFR4 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs148292303, COSV52801196, COSV52803650; called by muse, mutect2, varscan2
- LILRB1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.035); catalogued as rs955866600, COSV61120537; called by muse, mutect2, varscan2
- LRP2 | c.3617G>A p.R1206H | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs377534549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAP1L1 | c.1047T>A p.D349E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV99673941; called by muse, mutect2
- NAT2 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.337); catalogued as COSV54061604; called by muse, mutect2, varscan2
- NUP188 | c.2272C>A p.P758T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV65364908; called by muse, mutect2, varscan2
- OR4C6 | c.53A>C p.N18T | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as COSV58605011; called by muse, mutect2, varscan2
- OR5H2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs201934750; called by muse, mutect2, varscan2
- OR5J2 | c.767T>A p.I256N | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs139886298; called by muse, mutect2, varscan2
- PDC | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs368302911; called by muse, mutect2, varscan2
- PGM5 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs782344265; called by muse, mutect2, varscan2
- PPARGC1B | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs541164323, COSV58528411; called by muse, mutect2, varscan2
- PPP2R2C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1478956407, COSV58670452; called by muse, mutect2, varscan2
- RNF11 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs561210339; called by muse, mutect2, varscan2
- SLC27A6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs750563459; called by muse, mutect2, varscan2
- SLC6A14 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782404299, COSV64141364; called by muse, mutect2, varscan2
- SLC6A7 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 178/449 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs368125552; called by muse, mutect2, varscan2
- UNC80 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV99780529; called by muse, mutect2, varscan2
- WASHC4 | c.3031C>T p.R1011* | Nonsense Mutation (SNP) | VAF 86/232 reads (37%) | catalogued as COSV59890094; called by muse, mutect2, varscan2
- ZACN | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58036153; called by muse, mutect2, varscan2
- ZNF274 | c.1646C>T p.S549F (on ENST00000610905; = p.S444F on NM_016324.3) | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs747099920, COSV58767534; called by muse, mutect2, varscan2
- ZNF831 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100925935, COSV100926253; called by muse, mutect2, varscan2
- CAPNS1 | c.285_288del p.S95Rfs*26 | Frame Shift Del (DEL) | VAF 47/247 reads (19%) | called by mutect2, pindel, varscan2
- CENPJ | c.2897A>C p.E966A | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAAM1 | c.2663+1_2663+2del p.X888_splice | Splice Site (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- DCAF6 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DYNC1I1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- FMO5 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- LARS1 | c.476G>T p.G159V (on ENST00000394434 / NM_020117.11; = p.G132V on NM_016460.3) | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- LGSN | c.1164C>A p.D388E | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- LPL | c.543C>T p.G181= | Splice Region (SNP) | VAF 97/257 reads (38%) | called by muse, mutect2, varscan2
- LRRC7 | c.2267A>T p.H756L (on ENST00000651989 / NM_001370785.2; = p.H723L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- MED12L | c.3847_3855dup p.Q1283_Q1285dup | In Frame Ins (INS) | VAF 30/107 reads (28%) | called by mutect2, varscan2
- MYBPC1 | c.2768C>G p.S923* (on ENST00000550270 / NM_206820.2; = p.S930* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 61/237 reads (26%) | called by muse, mutect2, varscan2
- NEK11 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- OBSL1 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PLA2R1 | c.3407A>G p.Y1136C | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PLD3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PLEKHG7 | c.1833A>T p.R611S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SLC5A5 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 186/676 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SRPK1 | c.31del p.R11Efs*60 | Frame Shift Del (DEL) | VAF 109/331 reads (33%) | called by mutect2, pindel, varscan2
- STK17A | c.301del p.C101Vfs*5 | Frame Shift Del (DEL) | VAF 56/234 reads (24%) | called by mutect2, pindel, varscan2
- TENM2 | c.4830_4831del p.E1612Vfs*8 (on ENST00000518659 / NM_001122679.2; = p.E1373Vfs*8 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 43/131 reads (33%) | called by mutect2, pindel, varscan2
- TOPAZ1 | c.4663G>A p.A1555T | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.028); called by mutect2, varscan2
- TRIM36 | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF516 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP10 | c.1932G>A p.P644= | Silent (SNP) | VAF 60/183 reads (33%) | catalogued as rs374020706; called by muse, mutect2, varscan2
- ATP4A | c.2136C>T p.I712= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs748500240, COSV52865971, COSV52868425; called by muse, mutect2, varscan2
- C4orf54 | c.1665C>T p.R555= | Silent (SNP) | VAF 12/236 reads (5%) | catalogued as rs1018895130; called by muse, mutect2
- CAPN8 | c.69C>T p.N23= | Silent (SNP) | VAF 78/240 reads (33%) | catalogued as rs1298293702; called by muse, mutect2, varscan2
- CFAP43 | c.1188C>T p.I396= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs866251742, COSV53381265; called by muse, mutect2, varscan2
- CFAP74 | c.3207G>A p.G1069= | Silent (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2
- ENPP2 | c.645C>T p.Y215= | Silent (SNP) | VAF 79/185 reads (43%) | called by muse, mutect2, varscan2
- FLG | c.1206C>T p.R402= | Silent (SNP) | VAF 165/400 reads (41%) | catalogued as rs140941956; called by mutect2, varscan2
- GABRA3 | c.228C>T p.D76= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs201122592, COSV64798706; called by muse, mutect2, varscan2
- HLA-G | c.678G>A p.R226= | Silent (SNP) | VAF 115/278 reads (41%) | catalogued as rs1423127697, COSV64405935; called by muse, mutect2, varscan2
- KDM5C | c.3036C>A p.I1012= | Silent (SNP) | VAF 130/303 reads (43%) | called by muse, mutect2, varscan2
- KRT15 | c.231C>T p.F77= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs757053087, COSV54181609; called by muse, mutect2, varscan2
- LARGE1 | c.45G>A p.S15= | Silent (SNP) | VAF 192/244 reads (79%) | catalogued as rs752560976, COSV100505469; ClinVar: likely benign; called by muse, mutect2, varscan2
- LONRF3 | c.561C>T p.A187= | Silent (SNP) | VAF 139/353 reads (39%) | called by muse, mutect2, varscan2
- MAGEA6 | c.522C>T p.H174= | Silent (SNP) | VAF 12/314 reads (4%) | catalogued as rs1556826517, COSV61448746, COSV61448773; called by muse, mutect2
- NPAS3 | c.2616C>G p.L872= (on ENST00000356141 / NM_001164749.2; = p.L840= on NM_022123.3) | Silent (SNP) | VAF 183/450 reads (41%) | catalogued as COSV60825220; called by muse, mutect2, varscan2
- OR2A14 | c.369G>A p.A123= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as rs369022856; called by muse, mutect2, varscan2
- PCDHB3 | c.1644C>T p.R548= | Silent (SNP) | VAF 299/733 reads (41%) | catalogued as rs370431175; called by muse, mutect2, varscan2
- PLK3 | c.639G>A p.P213= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs745691603; called by muse, mutect2, varscan2
- POLR1B | c.945T>C p.P315= | Silent (SNP) | VAF 57/113 reads (50%) | called by muse, mutect2, varscan2
- PPL | c.1791C>T p.Y597= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as rs754559796; called by muse, mutect2, varscan2
- PRSS21 | c.324C>T p.S108= | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- PTH1R | c.1692C>T p.L564= | Silent (SNP) | VAF 66/187 reads (35%) | called by muse, mutect2, varscan2
- RSPH6A | c.1329C>T p.H443= | Silent (SNP) | VAF 121/428 reads (28%) | catalogued as rs778034228; called by muse, mutect2, varscan2
- STX11 | c.291C>T p.G97= | Silent (SNP) | VAF 146/337 reads (43%) | catalogued as COSV62449432; called by muse, mutect2, varscan2
- ZNF534 | c.1542G>A p.K514= (on ENST00000332323 / NM_001143939.3; = p.K501= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/222 reads (24%) | called by muse, mutect2
- ANKRD26P1 | n.611A>G | RNA (SNP) | VAF 25/49 reads (51%) | catalogued as rs558261492; called by muse, mutect2, varscan2
- CALM1 | c.-38C>T | 5'UTR (SNP) | VAF 80/166 reads (48%) | catalogued as rs1232709692; called by muse, mutect2, varscan2
- DGKI | c.2147+6438C>T | Intron (SNP) | VAF 20/146 reads (14%) | catalogued as rs753020642, COSV99938077; called by muse, mutect2, varscan2
- DNAH8 | c.-41-4547C>T | Intron (SNP) | VAF 39/106 reads (37%) | catalogued as rs368460226, COSV59492992; called by muse, mutect2, varscan2
- FOLH1 | c.118+389A>G | Intron (SNP) | VAF 63/152 reads (41%) | called by muse, mutect2, varscan2
- RNF44 | c.1237-83C>T | Intron (SNP) | VAF 72/182 reads (40%) | catalogued as rs1383810812; called by muse, mutect2, varscan2
